Somatic mutation profile of tumor specimen MMRF_2433_1_BM_CD138pos (aliquot MMRF_2433_1_BM_CD138pos_T1_KHS5U_L11087) from MMRF case MMRF_2433, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.9 years (19,701 days).
Specimen MMRF_2433_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e908258-3c7d-4d5c-9b37-c58fe1f12d13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2433_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2433_1_PB_Whole_C3_KHS5U_L11088; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97001e81-fa96-4f5c-8f6c-9c057b104ab2

The open-access MAF lists 93 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 25, Silent 11, 5'UTR 5, Intron 4, 3'Flank 4, Nonsense Mutation 3, 5'Flank 2, Frame Shift Ins 2, Splice Region 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCLAF3 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200297521, COSV61415203; called by muse, mutect2, varscan2
- CYP11B2 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1163029203, COSV100011566; called by muse, mutect2, varscan2
- FAM47C | c.648G>C p.E216D | Missense Mutation (SNP) | VAF 53/57 reads (93%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV63727687; called by muse, mutect2, varscan2
- FPR3 | c.406C>A p.H136N | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV59330078; called by muse, mutect2, varscan2
- KLHDC4 | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 156/315 reads (50%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV99566761; called by muse, mutect2, varscan2
- NRAS | c.190T>A p.Y64N | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54744579, COSV54745979; called by muse, varscan2
- RAF1 | c.567C>G p.N189K | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV52576657; called by muse, mutect2, varscan2
- SERPINB3 | c.475del p.I159Lfs*4 | Frame Shift Del (DEL) | VAF 29/91 reads (32%) | catalogued as COSV52192459; called by mutect2, pindel, varscan2
- ST3GAL3 | c.280G>A p.A94T (on ENST00000361392 / NM_174964.4; = p.A79T on NM_006279.5) | Missense Mutation (SNP) | VAF 87/170 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as rs778068441; called by muse, mutect2, varscan2
- ZIC1 | c.982+1G>T p.X328_splice | Splice Site (SNP) | VAF 156/315 reads (50%) | catalogued as rs763564912, COSV99292058; called by muse, mutect2, varscan2
- ANK1 | c.935C>A p.A312E | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHEK2 | c.1213dup p.C405Lfs*7 (on ENST00000382580 / NM_001005735.2; = p.C362Lfs*7 on NM_007194.4) | Frame Shift Ins (INS) | VAF 47/76 reads (62%) | called by mutect2, pindel, varscan2
- DDX21 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 136/300 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DHX9 | c.3535A>G p.S1179G | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH14 | c.5512G>A p.V1838M (on ENST00000445597; = p.V2259M on NM_001367479.1) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- DVL1 | c.1073T>C p.I358T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- EP400 | c.2488C>A p.L830M | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXP2 | c.1978C>A p.P660T | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FRAS1 | c.6648G>T p.K2216N | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- H2AC6 | c.366_367insCG p.S123Rfs*15 | Frame Shift Ins (INS) | VAF 138/381 reads (36%) | called by mutect2, pindel, varscan2
- HCFC2 | c.984_1006del p.Y328* | Nonsense Mutation (DEL) | VAF 50/139 reads (36%) | called by mutect2, pindel, varscan2
- HMCN1 | c.8123G>A p.W2708* | Nonsense Mutation (SNP) | VAF 109/254 reads (43%) | called by muse, mutect2, varscan2
- HOXD11 | c.30C>A p.S10R | Missense Mutation (SNP) | VAF 133/251 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, varscan2
- L3MBTL1 | c.166A>G p.S56G (on ENST00000418998 / NM_001377303.1; = p.S34G on NM_032107.5) | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- MAST4 | c.6791T>C p.I2264T (on ENST00000403625 / NM_001164664.2; = p.I2075T on NM_015183.3) | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDN1 | c.3890A>G p.H1297R | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MGAM | c.3514T>A p.Y1172N | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MYT1 | c.2010C>G p.D670E | Missense Mutation (SNP) | VAF 125/305 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRAS | c.258T>A p.N86K | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.069); called by muse, varscan2
- OR7D4 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 129/248 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- PDZD2 | c.7750G>T p.A2584S | Missense Mutation (SNP) | VAF 80/168 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRKD2 | c.1277T>G p.I426S | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- SLC38A7 | c.1358C>G p.A453G | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SMC4 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.78); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SMPD4BP | n.1736G>C | Splice Region (SNP) | VAF 61/134 reads (46%) | called by muse, mutect2, varscan2
- SYT17 | c.1139T>A p.L380* | Nonsense Mutation (SNP) | VAF 50/123 reads (41%) | called by muse, mutect2, varscan2
- TET1 | c.3187C>G p.L1063V | Missense Mutation (SNP) | VAF 185/431 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TMEM240 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- UBR5 | c.5731A>C p.M1911L | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBR5 | c.5730G>T p.M1910I | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF41 | c.1147T>G p.Y383D | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- BTN2A2 | c.591C>T p.S197= | Silent (SNP) | VAF 73/157 reads (46%) | called by muse, mutect2
- CARNS1 | c.1755G>A p.E585= | Silent (SNP) | VAF 118/266 reads (44%) | catalogued as rs1565138829; called by muse, mutect2, varscan2
- HTR3C | c.915C>T p.T305= | Silent (SNP) | VAF 85/220 reads (39%) | called by muse, mutect2, varscan2
- IGLC2 | c.300G>A p.V100= | Silent (SNP) | VAF 84/303 reads (28%) | catalogued as rs1234728020; called by muse, mutect2, varscan2
- MDGA2 | c.2724C>T p.F908= (on ENST00000399232 / NM_001113498.2; = p.F610= on NM_182830.4) | Silent (SNP) | VAF 95/192 reads (49%) | catalogued as COSV62085136; called by muse, mutect2, varscan2
- MOCS3 | c.123A>G p.E41= | Silent (SNP) | VAF 93/233 reads (40%) | catalogued as rs752192851, COSV99724120; called by muse, mutect2, varscan2
- OR7G2 | c.294G>C p.T98= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs377637744; called by muse, mutect2, varscan2
- PCARE | c.2802C>A p.P934= | Silent (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.2019T>C p.D673= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as rs768781136; called by muse, mutect2, varscan2
- SHANK3 | c.3072C>T p.S1024= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as rs1412473238; called by muse, mutect2, varscan2
- TVP23A | c.240A>G p.V80= | Silent (SNP) | VAF 101/183 reads (55%) | called by muse, mutect2, varscan2
- AIFM3 | c.1758-66G>T | Intron (SNP) | VAF 52/101 reads (51%) | called by muse, mutect2, varscan2
- ANKRD13C | c.-221T>A | 5'UTR (SNP) | VAF 67/134 reads (50%) | called by muse, mutect2, varscan2
- ATP5MC3 | c.*384A>G | 3'UTR (SNP) | VAF 55/121 reads (45%) | called by muse, mutect2, varscan2
- ATP8A1 | c.*2146T>A | 3'UTR (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- BRINP2 | c.*174G>A | 3'UTR (SNP) | VAF 40/68 reads (59%) | catalogued as rs1425258802; called by muse, varscan2
- CASP2 | c.*1198T>G | 3'UTR (SNP) | VAF 8/15 reads (53%) | called by muse, varscan2
- CAV3 | c.*231G>C | 3'UTR (SNP) | VAF 76/157 reads (48%) | catalogued as COSV100373266; called by muse, mutect2, varscan2
- CAVIN2 | c.*1000G>T | 3'UTR (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- CBLN4 | c.-447C>A | 5'UTR (SNP) | VAF 76/175 reads (43%) | called by muse, mutect2, varscan2
- CC2D2B | chr10:96033045 A>T | 3'Flank (SNP) | VAF 49/88 reads (56%) | called by muse, mutect2, varscan2
- CDS2 | c.*6453T>C | 3'UTR (SNP) | VAF 53/100 reads (53%) | catalogued as rs190603181; called by muse, mutect2, varscan2
- CHRDL1 | c.*2023G>A | 3'UTR (SNP) | VAF 68/75 reads (91%) | called by muse, mutect2, varscan2
- DDHD1 | c.551-106A>G | Intron (SNP) | VAF 13/19 reads (68%) | called by muse, mutect2, varscan2
- DNASE1L3 | c.230+110A>G | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2
- ELAPOR2 | c.*2565T>C | 3'UTR (SNP) | VAF 48/103 reads (47%) | called by muse, mutect2, varscan2
- EXOC5 | c.*547G>T | 3'UTR (SNP) | VAF 29/79 reads (37%) | called by muse, mutect2, varscan2
- GABRA6 | c.*30A>C | 3'UTR (SNP) | VAF 55/103 reads (53%) | called by muse, mutect2, varscan2
- GAS8 | c.*921C>T | 3'UTR (SNP) | VAF 144/316 reads (46%) | called by muse, mutect2, varscan2
- GRID2IP | chr7:6497568 C>T | 3'Flank (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- HIPK1 | c.*2141C>T | 3'UTR (SNP) | VAF 14/34 reads (41%) | called by mutect2, varscan2
- IGFBP4 | c.*147C>T | 3'UTR (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- KIF3B | c.*857A>T | 3'UTR (SNP) | VAF 37/94 reads (39%) | called by muse, mutect2, varscan2
- LCE2D | c.*33G>C | 3'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- LUZP2 | c.-8G>T | 5'UTR (SNP) | VAF 55/119 reads (46%) | called by muse, mutect2, varscan2
- MAMDC2 | c.*553T>A | 3'UTR (SNP) | VAF 44/100 reads (44%) | called by muse, mutect2, varscan2
- MMP2 | c.-35C>A | 5'UTR (SNP) | VAF 3/39 reads (8%) | catalogued as COSV99527833; called by muse, mutect2
- NT5DC3 | c.*331G>A | 3'UTR (SNP) | VAF 88/171 reads (51%) | called by muse, mutect2
- PCSK5 | c.1900+222C>A | Intron (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- PPM1L | chr3:160756095 C>A | 5'Flank (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- PREX2 | c.*5575T>C | 3'UTR (SNP) | VAF 42/72 reads (58%) | called by muse, mutect2, varscan2
- PROS2P | n.1893A>T | RNA (SNP) | VAF 76/154 reads (49%) | called by muse, mutect2, varscan2
- SHOX | c.*582G>T | 3'UTR (SNP) | VAF 59/112 reads (53%) | called by muse, mutect2, varscan2
- SRI | c.*932_*936del | 3'UTR (DEL) | VAF 37/98 reads (38%) | called by mutect2, pindel, varscan2
- TECRL | chr4:64275869 C>T | 3'Flank (SNP) | VAF 45/86 reads (52%) | called by muse, mutect2, varscan2
- TMEM30B | c.*316C>G | 3'UTR (SNP) | VAF 46/121 reads (38%) | called by muse, mutect2, varscan2
- TPT1 | chr13:45341374 del G | 5'Flank (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- VAV3 | c.*192T>G | 3'UTR (SNP) | VAF 49/104 reads (47%) | called by muse, mutect2, varscan2
- VAX1 | chr10:117128680 C>A | 3'Flank (SNP) | VAF 64/135 reads (47%) | called by muse, mutect2, varscan2
- ZNF141 | c.*9525G>A | 3'UTR (SNP) | VAF 182/375 reads (49%) | called by muse, mutect2, varscan2
- ZNF197 | c.*3044T>C | 3'UTR (SNP) | VAF 49/104 reads (47%) | called by muse, mutect2, varscan2
- ZNF391 | c.-503G>T | 5'UTR (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
